Gene-level copy-number profile of tumor specimen C3N-00204-02 (profiled together with C3N-00204-03, C3N-00204-04) from CPTAC case C3N-00204, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 63.0 years (23,017 days).
Specimen C3N-00204-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 521102b3-fa4d-4ad9-896f-36887153d43b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00204-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/543382b6-e304-437e-baa9-24a2bd45bece

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 21,083; copy number 2: 31,387; copy number 3: 5,481; copy number 4: 97; copy number 5: 9; copy number 7: 1; copy number 8: 8; copy number 9: 110; copy number 12: 3; copy number 13: 13; copy number 14: 1; copy number 16: 1; copy number 17: 118; copy number 20: 12; copy number 24: 4; copy number 27: 5; copy number 32: 3.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,249,777–1,280,420, 3 genes: AL162741.1, UBE2J2, LINC01786.
- chr1:247,085,389–247,175,525, 6 genes: AL627095.1, ZNF669, C1orf229, FGFR3P6, ZNF124, AL390728.3.
- chr2:63,232,453–63,233,577, 1 gene (within-gene range 0–2): MTFR2P1.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:64,878,790–64,889,063, 2 genes: AC125634.1, RNU6-1293P.
- chr13:48,303,744–48,599,436, 9 genes (within-gene range 0–2): RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 288 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:99,412,261–99,498,698, 2 genes, copy number 5: ADH7, AP001960.1.
- chr7:114,922,359–117,230,176, 44 genes, copy number 8–32 (within-gene range 2–32): MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2.
- chr8:150,584–167,043, 3 genes, copy number 5: AC131281.2, WBP1LP3, OR4F21.
- chr9:137,243,584–137,253,497, 3 genes, copy number 5 (within-gene range 2–5): FAM166A, STPG3-AS1, STPG3.
- chr15:90,839,641–90,853,608, 1 gene, copy number 5: AC124248.1.
- chr17:18,225,635–22,706,703, 235 genes, copy number 7–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,288. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
